Gene-level copy-number profile of tumor specimen TCGA-UP-A6WW-01A from TCGA case TCGA-UP-A6WW, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; Tumor grade: G2; Age at diagnosis: 58.7 years (21,427 days).
Specimen TCGA-UP-A6WW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.aeaf677b-7628-47a1-bcf2-72e09f9c02a0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-UP-A6WW-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7bf8f9f9-a99e-4c4d-a769-804a118d14e8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 24; copy number 1: 15,579; copy number 2: 42,906; copy number 3: 1,308.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-UP-A6WW-01A-12D-A34I-01): tumor purity 0.84, ploidy 1.79, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 24 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:48,303,744–48,599,436, 1 gene (within-gene range 0–1): RB1.
- chr13:48,429,269–48,771,827, 8 genes: Metazoa_SRP, RCBTB2, AL157813.2, AL157813.1, LINC01077, LINC00462, CYSLTR2, PSME2P2.
- chr16:50,783,859–51,151,367, 12 genes: AC007728.1, LINC02168, LINC02128, AC025810.1, RNA5SP426, LINC02127, AC027688.1, AC027688.2, AC009166.3, SOD1P2, SALL1, AC009166.1.
- chr16:51,176,066–51,268,117, 3 genes: AC009166.2, AC137494.1, AC137527.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 13,192. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
